Somatic mutation profile of tumor specimen MBCProject_4012_T1_WES (aliquot MBCProject_4012_T1_WES_1) from CMI case MBCProject_4012, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.7 years (18,155 days).
Specimen MBCProject_4012_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8140461-bdb7-45ec-8c57-461ea75c50c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4012_SALIVA (Saliva), aliquot MBCProject_4012_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d62506e6-a937-491d-87d0-738077e6ab46

The open-access MAF lists 100 somatic variants for this specimen: 59 protein-altering or splice-affecting, 26 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 26, Intron 10, Frame Shift Ins 3, RNA 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, In Frame Ins 1, 3'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.973G>T p.G325* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as rs863224500, COSV52982163, COSV53644278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1237724154; called by muse, mutect2, varscan2
- ACE | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs767340249; called by muse, mutect2, varscan2
- ACLY | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs782737276; called by muse, mutect2, varscan2
- ANKRD11 | c.3442G>A p.G1148S | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143417087; called by muse, mutect2, varscan2
- APOB | c.13153C>A p.R4385S | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as CM125433, COSV51949532; called by muse, mutect2, varscan2
- CAPN2 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 66/563 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as rs370722848; called by muse, mutect2, varscan2
- CDH9 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50341777; called by muse, mutect2, varscan2
- CFAP46 | c.8044G>T p.V2682F | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99585118; called by muse, mutect2, varscan2
- CNTN5 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199794950, COSV54285547, COSV54309805; called by muse, varscan2
- COL17A1 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs371044491, COSV62225589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.3403C>T p.R1135C (on ENST00000297405 / NM_001363185.1; = p.R1031C on NM_052900.3) | Missense Mutation (SNP) | VAF 54/1081 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369628503, COSV52108004; called by muse, mutect2
- ELOA2 | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1437805724, COSV55295420; called by muse, mutect2, varscan2
- EPHA2 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs369180720; called by muse, mutect2, varscan2
- FNDC3B | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV61050729; called by muse, mutect2, varscan2
- GCNT1 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs928724563, COSV65058830; called by muse, mutect2, varscan2
- HOXA4 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982239162, COSV100415725; called by muse, mutect2, varscan2
- IGSF1 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.369); catalogued as rs1489517476, COSV100812204; called by muse, mutect2, varscan2
- IRF8 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs149439061; called by muse, mutect2, varscan2
- KIF14 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs142004534; called by muse, mutect2, varscan2
- LRRC74A | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs61733959; called by muse, mutect2, varscan2
- MUC5B | c.14735G>A p.S4912N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV71591280; called by muse, mutect2, varscan2
- NPAP1 | c.2419G>T p.V807L | Missense Mutation (SNP) | VAF 96/164 reads (59%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.188); catalogued as COSV61504697; called by muse, mutect2, varscan2
- OR5T2 | c.545del p.P182Hfs*70 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV57587840, COSV57588928; called by mutect2, pindel, varscan2
- RAB40B | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200202167; called by muse, mutect2, varscan2
- TSHZ3 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1210168815, COSV53666665, COSV53678557; called by muse, mutect2, varscan2
- USH2A | c.8096G>A p.R2699Q | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748137104, COSV56407176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPNPEP2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769016610; called by muse, mutect2, varscan2
- ZBTB34 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as rs1202990571; called by muse, mutect2, varscan2
- AMPH | c.1946T>C p.V649A | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD12 | c.2473C>G p.R825G | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CFAP46 | c.3618G>C p.Q1206H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.186); called by muse, mutect2
- FANCI | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- GCN1 | c.2355C>A p.D785E | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- IDH3A | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK18 | c.1144G>C p.V382L | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KDR | c.798+2T>C p.X266_splice | Splice Site (SNP) | VAF 52/259 reads (20%) | called by muse, mutect2, varscan2
- MAP2 | c.5038A>G p.T1680A | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MYB | c.536dup p.N179Kfs*63 | Frame Shift Ins (INS) | VAF 35/183 reads (19%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.5249C>T p.P1750L | Missense Mutation (SNP) | VAF 117/417 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCYT1A | c.565+1G>C p.X189_splice | Splice Site (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- PDXDC1 | c.1429C>A p.Q477K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHC3 | c.2458T>A p.F820I (on ENST00000494943 / NM_001308116.2; = p.F832I on NM_024947.4) | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PRAMEF2 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PYCR2 | c.861A>T p.L287F | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- RAD17 | c.1568C>G p.P523R (on ENST00000380774 / NM_133339.2; = p.P512R on NM_002873.1) | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RGS2 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 272/776 reads (35%) | called by muse, mutect2, varscan2
- SCYL3 | c.1832_1833dup p.M613Lfs*44 (on ENST00000367770; = p.M559Lfs*44 on NM_020423.7) | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- SDR16C5 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC16B | c.3170C>G p.T1057S | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- SH2B3 | c.1613_1615dup p.S538_L539insR | In Frame Ins (INS) | VAF 38/424 reads (9%) | called by mutect2, pindel
- SIPA1L3 | c.4738C>G p.P1580A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SNAP25 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SOS2 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- STMN3 | c.114G>C p.G38= | Splice Region (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- TPCN2 | c.347dup p.P117Sfs*66 | Frame Shift Ins (INS) | VAF 34/258 reads (13%) | called by mutect2, varscan2
- UBR5 | c.2441A>T p.D814V | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- XPR1 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF584 | c.1214C>G p.T405S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS2 | c.3078C>G p.G1026= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- ARPP21 | c.1533C>T p.S511= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs562602597; called by muse, mutect2, varscan2
- BTN1A1 | c.1350C>T p.V450= | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- C1QL4 | c.531C>T p.N177= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as rs192995889; called by muse, varscan2
- CEP120 | c.1167C>T p.H389= | Silent (SNP) | VAF 48/265 reads (18%) | called by muse, mutect2, varscan2
- COQ10A | c.528C>T p.F176= | Silent (SNP) | VAF 36/222 reads (16%) | called by muse, mutect2, varscan2
- CX3CR1 | c.612G>A p.L204= | Silent (SNP) | VAF 40/229 reads (17%) | catalogued as rs780606575; called by muse, mutect2, varscan2
- EPYC | c.210C>T p.L70= | Silent (SNP) | VAF 76/327 reads (23%) | called by muse, mutect2, varscan2
- FMN1 | c.3645C>G p.V1215= (on ENST00000616417 / NM_001277313.2; = p.V992= on NM_001103184.4) | Silent (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- GRIA1 | c.1881C>T p.I627= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as COSV99598807; called by muse, mutect2, varscan2
- GRM4 | c.1209G>A p.E403= | Silent (SNP) | VAF 77/140 reads (55%) | catalogued as rs1423211961, COSV65213751, COSV65214306; called by muse, mutect2, varscan2
- LAMC1 | c.1092G>C p.G364= | Silent (SNP) | VAF 49/366 reads (13%) | called by muse, mutect2, varscan2
- LRRC20 | c.312G>T p.L104= (on ENST00000355790 / NM_207119.3; = p.L54= on NM_018239.4) | Silent (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- NDUFV3 | c.147C>G p.S49= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as COSV100446943; called by muse, mutect2, varscan2
- OBSCN | c.20727G>A p.G6909= | Silent (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.555C>T p.Y185= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs985147302, COSV53870995; called by muse, varscan2
- PCOLCE2 | c.441C>T p.N147= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs753153268, COSV56001253, COSV99930916; called by muse, mutect2
- PHLPP1 | c.768C>T p.A256= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- POGZ | c.159G>C p.V53= | Silent (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- RIMBP2 | c.222C>T p.S74= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs753685683, COSV99898353; called by muse, mutect2, varscan2
- SLIT2 | c.811T>C p.L271= | Silent (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- SV2C | c.1837C>T p.L613= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs1304181394; called by muse, mutect2, varscan2
- TCAF1 | c.291C>T p.S97= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV63518009; called by muse, mutect2, varscan2
- USP17L7 | c.1464C>T p.N488= | Silent (SNP) | VAF 36/742 reads (5%) | called by muse, mutect2
- USP31 | c.3933C>G p.S1311= | Silent (SNP) | VAF 41/374 reads (11%) | called by muse, mutect2, varscan2
- WAS | c.333C>G p.T111= | Silent (SNP) | VAF 94/359 reads (26%) | called by muse, mutect2, varscan2
- BET1 | c.20-371T>G | Intron (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- DENND3 | c.956+2304T>G | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- LY6G6E | c.178+26C>G | Intron (SNP) | VAF 72/200 reads (36%) | called by muse, varscan2
- MS4A4E | c.144+1302G>T | Intron (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- MYRF | c.46+2625C>T | Intron (SNP) | VAF 66/122 reads (54%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1863G>A | RNA (SNP) | VAF 30/255 reads (12%) | catalogued as rs750363409; called by muse, mutect2, varscan2
- OR2L1P | n.864C>T | RNA (SNP) | VAF 88/308 reads (29%) | catalogued as rs72763231; called by muse, mutect2, varscan2
- PNKP | c.578+22G>A | Intron (SNP) | VAF 49/480 reads (10%) | called by muse, mutect2
- PNKP | c.578+20G>A | Intron (SNP) | VAF 50/494 reads (10%) | called by muse, mutect2
- PXN | c.831+1640C>T | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs1413190195; called by muse, mutect2
- SP140 | c.406+444C>G | Intron (SNP) | VAF 42/307 reads (14%) | catalogued as rs550223117; called by muse, mutect2, varscan2
- TMEM132E | chr17:34578964 G>A | 5'Flank (SNP) | VAF 10/45 reads (22%) | catalogued as rs781715046; called by muse, mutect2, varscan2
- TNFAIP2 | c.*477A>T | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- TRAF3IP2 | c.19+3297C>A | Intron (SNP) | VAF 47/295 reads (16%) | called by muse, mutect2, varscan2
- XIST | n.8692C>T | RNA (SNP) | VAF 101/329 reads (31%) | called by muse, mutect2, varscan2
